Somatic mutation profile of tumor specimen TCGA-AB-2862-03B (aliquot TCGA-AB-2862-03B-01W-0728-08) from TCGA case TCGA-AB-2862, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.6 years (12,266 days).
Specimen TCGA-AB-2862-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2b0669-79cf-47d3-afe9-ca7f89056457.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2862-11B (Solid Tissue Normal), aliquot TCGA-AB-2862-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/041e2e3f-9452-48a5-950f-483d70618cb7

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIAPH3 | c.627-2A>T p.X209_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | catalogued as rs1266505101; called by muse, mutect2
- EYA4 | c.963C>A p.N321K | Missense Mutation (SNP) | VAF 116/274 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV62047462; called by muse, mutect2, varscan2
- HECW1 | c.3815G>A p.R1272Q | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs367661051, COSV67824610; called by muse, mutect2, varscan2
- NCCRP1 | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 225/499 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778542772, COSV59212310; called by muse, mutect2, varscan2
- TCEANC | c.136A>G p.T46A (on ENST00000380600 / NM_001297563.2; = p.T76A on NM_152634.4) | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59039425; called by muse, mutect2, varscan2
- TCERG1L | c.1699T>C p.F567L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs758709491, COSV64047697; called by muse, mutect2, varscan2
- ADCY5 | c.1251G>A p.A417= | Silent (SNP) | VAF 36/77 reads (47%) | catalogued as rs200302997, COSV59195404; called by muse, mutect2, varscan2
- AKAP13 | c.714G>A p.P238= | Silent (SNP) | VAF 84/259 reads (32%) | catalogued as rs374214307; called by muse, mutect2, varscan2
- ARFGEF2 | c.1542G>A p.V514= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV64211126; called by muse, mutect2, varscan2
- BCAR3 | c.1416C>T p.G472= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs1318249864, COSV53073006; called by muse, mutect2, varscan2
